Surgical pathology report (de-identified scan), TCGA case TCGA-39-5029, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5029-01A (Primary Tumor).

[page 1 of 7]
Clinical Diagnosis & History:

with right lower lobe mass and cervical adenopathy.
thoracotomy and lobectomy.

Specimens Submitted:

- 1: SP: Level seven mediastinal lymph nodes
- 2: SP: Tissue external from bronchus intermedius
- 3: SP: Right level eleven interlobar lymph node
- 4: SP: Right level ten mediastinal lymph node
- 5: SP: Bronchial margin bronchus intermedius
- 6: SP: Level seven mediastinal lymph nodes #2
- 7: SP: Right level eleven interlobar lymph node #2
- 8: SP: Right middle and lower lobe lung
- 9: SP: Portion of fifth rib
- 10: SP: Portion of fourth rib
- 11: SP: Right level four lymph nodes

DIAGNOSIS:

- 1) LYMPH NODES, MEDIASTINUM LEVEL VII, EXCISION:
- METASTATIC SQUAMOUS CELL CARCINOMA.
- 2) "TISSUE, EXTERNAL FROM BRONCHUS INTERMEDIUS", EXCISION:
- BENIGN FIBROCONNECTIVE TISSUE.
- 3) LYMPH NODE, RIGHT INTERLOBAR LEVEL XI, EXCISION:
- METASTATIC SQUAMOUS CELL CARCINOMA.
- 4) LYMPH NODE, RIGHT MEDIASTINUM LEVEL X, EXCISION:
- FRAGMENTS OF BENIGN LYMPH NODES.
- 5) BRONCHIAL MARGIN, BRONCHUS INTERMEDIUS, EXCISION:
- BENIGN BRONCHIAL TISSUE WITH SQUAMOUS METAPLASIA.
- 6) - LYMPH NODE #2, MEDIASTINUM LEVEL VII, EXCISION:
- METASTATIC SQUAMOUS CELL CARCINOMA.
- 7) LYMPH NODE #2, RIGHT INTERLOBAR LEVEL XI, EXCISION:
- METASTATIC SQUAMOUS CELL CARCINOMA.

** Continued on next page **

[page 2 of 7]
- 8) LUNG, RIGHT MIDDLE AND LOWER LOBES, BILOBECTOMY:
- SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED, INVOLVING PERIBRONCHIAL RIGHT LOWER LOBE.
- THE TUMOR MEASURES 3 X 2.7 X 2.5 CM.
- VASCULAR INVASION IS PRESENT.
- PERINEURAL INVASION IS PRESENT.
- THE MAINSTEM BRONCHUS IS NOT INVOLVED BY TUMOR.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE PLEURA IS FREE OF TUMOR.
- THE NON-NEOPLASTIC LUNG SHOWS THE FOLLOWING ABNORMALITIES: FOCAL OBSTRUCTIVE PNEUMONITIS, FOCAL ATELECTASIS AND EMPHYSEMATOUS CHANGES.
- LYMPH NODES: ONE OUT OF THREE LYMPH NODES ARE POSITIVE FOR METASTATIC SQUAMOUS CELL CARCINOMA (1/3).
- 9) BONE, PORTION OF 5TH RIB, EXCISION;
- BENIGN BONE, SKELETAL MUSCLE AND BONE MARROW HEMATOPOIETIC ELEMENTS.
- 10) BONE, PORTION OF 4TH RIB, EXCISION:
- BENIGN BONE AND BONE MARROW HEMATOPOIETIC ELEMENTS.
- 11) LYMPH NODE, RIGHT LEVEL IV, EXCISION:
- METASTATIC SQUAMOUS CELL CARCINOMA.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1). The specimen is received fresh, labeled "level 7 mediastinal lymph nodes" and consists of a 4.5 x 3.5 x 1.5 cm segment of red soft tissue. Upon sectioning the specimen, a 3.5 cm nodule is identified. A representative portion is frozen. Another representative section is submitted.

Summary of sections:
FSC frozen section control
U - undesignated

2). The specimen is received fresh for frozen section consultation, labeled "Tissue external from bronchus intermedius" and consists of an irregular shaped fragment of red tan soft tissue measuring 1 x 0.7 x 0.3 cm. Entirely submitted for frozen section.

** Continued on next page **

[page 3 of 7]
Summary of sections:

FSC -- frozen section control

3). The specimen is received fresh for frozen section consultation, labeled "Right level 11 interlobar lymph node" and consists of a matted black lymph nodes measuring 2.5 x 2.2 x 1.2 cm. Representative submitted for frozen section. The remaining specimen is trisected and entirely submitted for permanent section.

Summary of sections:

FSC -- frozen section control
TRI-trisected remaining tissue

4). The specimen is received fresh for frozen section consultation, labeled "Right level ten mediastinal lymph node" and consists of one piece of black lymph node measuring 2 cm in greatest dimension. Bisected and entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

5). The specimen is received fresh for frozen section consultation, labeled "bronchial margin bronchus intermedius" and consists of a red tan bronchial ring measuring 2 cm in diameter and 0.4 cm in thickness. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

6). The specimen is received in formalin labeled "Level 7 mediastinal lymph nodes in region". It consists of a single anthracotic lymph node measuring 4 x 2 x 1.5. On cut section of the lymph node, it is white-tan and firm. Representative sections are submitted.

Summary of sections:

U-undesignated

7). The specimen is received in formalin labeled "Right level 11 interlobar lymph node number two". It consists of a 1.2 x 0.7 x 0.5 cm lymph node which is bisected and submitted entirely.

summary of sections:

U-undesignated

** Continued on next page **

[page 4 of 7]
8). The specimen is received fresh and is labeled "right middle and lower lobe lung". It consists of a 17.5 x 12.0 x 4.5 cm lobectomy specimen of a right lung including middle and lower lobes. There are attached bronchus and blood vessels straddled by multiple staple lines, which weighs 306 gm. The attached bronchus measures 3 cm in length and 1.5 cm in greatest diameter. The pleural surface is smooth, glistening and is inked black. Serial sectioning reveals a 3.0 x 2.7 x 2.5 cm white-tan ill-defined tumor.

The tumor is situated in the proximal lung parenchyma, located approximately 0.5 cm from the bronchial margin and 1 cm from the closest staple line. The tumor grossly involves the bronchial wall with resulting bronchial obstruction. The bronchial mucosa is smooth and granular. The remaining pulmonary parenchyma is unremarkable grossly with no additional tumor identified. The staple lines are removed, and the surgical margins underneath the staple lines are inked blue, shaved and entirely submitted. Peribronchial anthracotic lymph nodes are identified and submitted. Representative sections are submitted. TPS is submitted. Photographs are taken.

Summary of sections:

BM -- bronchial margin.

VM -- vascular margin.

SM -- staple margin.

TP -- tumor with pleura.

TB -- tumor with bronchus

TU -- tumor with adjacent pulmonary parenchyma.

RA - random lung parenchyma at least 3 cm away from main tumor

RC - random lung parenchyma close to tumor (within 3 cm of main tumor)

LN -- lymph nodes.

9). The specimen is received in formalin labeled "Portion of fifth rib". It consists of a segment of rib measuring 6.5 x 2 x 1.5 cm. There is an attached segment of pleura measuring 4 x 2.5 x 0.5 cm. Representative sections are submitted after decalcification.

Summary of sections:

U-undesignated

B-bone

10). The specimen is received in formalin, labeled "portion of fourth rib" and consists of a fragment of rib with attached soft tissue measuring 6.5 cm in length and 2.5 cm in diameter. Representatively submitted.

Summary sections:

R - rib, for decalcification

S - soft tissue

11) The specimen is received in formalin, labeled "right level 4 lymph nodes" and consists of multiple anthracotic tan firm lymph nodes ranging from 0.4 to 1.2 cm in greatest dimension along with a matted mass of lymph

** Continued on next page **

[page 5 of 7]
nodes measuring 2.8 x 1.2 x 0.8 cm. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph nodes
MLN -- matted lymph nodes

Summary of Sections:

Part 1: SP: Level seven mediastinal lymph nodes

Block	Sect. Site	PCs
1	FSC	1
1	U	1

Part 2: SP: Tissue external from bronchus intermedius

Block	Sect. Site	PCs
1	FSC	1

Part 3: SP: Right level eleven interlobar lymph node

Block	Sect. Site	PCs
1	FSC	1
3	RLN	3

Part 4: SP: Right level ten mediastinal lymph node

Block	Sect. Site	PCs
1	FSC	1

Part 5: SP: Bronchial margin bronchus intermedius

Block	Sect. Site	PCs
1	FSC	1

Part 6: SP: Level seven mediastinal lymph nodes #2

Block	Sect. Site	PCs
1	U	1

Part 7: SP: Right level eleven interlobar lymph node #2

Block	Sect. Site	PCs
1	u	1

Part 8: SP: Right middle and lower lobe lung

Block	Sect. Site	PCs
-------	------------	-----

** Continued on next page **

[page 6 of 7]
1	BM	1
2	LN	2
2	RA	2
2	RC	2
3	SM	3
3	TB	3
1	TP	1
4	TU	4
1	VM	1

Part 9: SP: Portion of Fifth rib

Block	Sect.	Site	PCs
1	b		1
1	u		1

Part 10: SP: Portion of fourth rib

Block	Sect.	Site	PCs
1	R		1
1	S		1

Part 11: SP: Right level four lymph nodes

Block	Sect.	Site	PCs
1	BLN		2
3	LN		10
2	MLN		3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: POSITIVE FOR NON-SMALL CELL CARCINOMA.
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME
- 3) FROZEN SECTION DIAGNOSIS: METASTATIC NON-SMALL CELL CARCINOMA.
PERMANENT DIAGNOSIS: SAME
- 4) FROZEN SECTION DIAGNOSIS: NO CARCINOMA SEEN.
PERMANENT DIAGNOSIS: SAME
- 5) FROZEN SECTION DIAGNOSIS: SEVERELY DYSPLASTIC RESPIRATORY EPITHELIUM ARISING TO THE LEVEL OF IN-SITU CARCINOMA.
PERMANENT DIAGNOSIS: SEE FINAL

** Continued on next page **

[page 7 of 7]
**** End of Report ****

Source: NCI Genomic Data Commons file e234b88c-bae3-4b57-969d-88b37203659a (TCGA-39-5029.61C4772E-24FF-4B25-94D2-2D8E64C4753A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).